Somatic mutation profile of tumor specimen MMRF_1931_1_BM_CD138pos (aliquot MMRF_1931_1_BM_CD138pos_T1_KHS5U_L08114) from MMRF case MMRF_1931, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,526 days).
Specimen MMRF_1931_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36dfa3e4-ef03-44e1-9f41-b5bf2475e21c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1931_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1931_1_PB_WBC_C2_KHS5U_L08115; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3935a775-344b-4ca2-9e7a-47bf8145c548

The open-access MAF lists 134 somatic variants for this specimen: 63 protein-altering or splice-affecting, 19 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 36, Silent 19, Intron 7, 5'UTR 5, Splice Site 3, Splice Region 3, 5'Flank 2, Nonsense Mutation 2, RNA 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB2 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs967357807, COSV101187113; called by muse, mutect2, varscan2
- ATRNL1 | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372322547; called by muse, mutect2, varscan2
- BCOR | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV60723135; called by muse, mutect2, varscan2
- DHRS7C | c.847G>A p.A283T (on ENST00000330255 / NM_001220493.2; = p.A282T on NM_001105571.3) | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1308907842, COSV57652697; called by muse, mutect2, varscan2
- DPEP3 | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1395269661; called by muse, mutect2, varscan2
- EPHB4 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs920403132, COSV62267993; called by muse, mutect2, varscan2
- ERBB3 | c.3926G>A p.R1309H | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747453114, COSV57256533; called by muse, mutect2, varscan2
- GPR152 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV56888028; called by muse, mutect2, varscan2
- IGHJ1 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 30/38 reads (79%) | catalogued as rs1381030792; called by muse, varscan2
- IGHJ4 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 50/72 reads (69%) | PolyPhen benign (0.005); catalogued as rs537730557; called by muse, varscan2
- IGHV2-70 | c.69G>C p.L23F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569950662; called by muse, varscan2
- IGHV2-70 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs182292946; called by muse, varscan2
- IGHV2-70 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs767674828; called by muse, varscan2
- IGKV4-1 | c.182G>C p.W61S | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778196241; called by muse, mutect2, varscan2
- IGLL5 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); catalogued as rs763031578, COSV104440262; called by muse, mutect2, varscan2
- KCNC2 | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs746501735, COSV54361296; called by muse, mutect2, varscan2
- KCNIP4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as rs755301537; called by muse, mutect2, varscan2
- LCOR | c.4006G>T p.D1336Y | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1290515397; called by muse, mutect2, varscan2
- LILRA1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.04); catalogued as rs376376360; called by muse, varscan2
- MROH2A | c.1139-1G>A p.X380_splice | Splice Site (SNP) | VAF 37/125 reads (30%) | catalogued as rs991786126; called by muse, mutect2, varscan2
- NDST1 | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV55790379; called by muse, mutect2, varscan2
- NOS1 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs754035678, COSV57615840; called by muse, mutect2, varscan2
- NUP155 | c.2574_2579del p.H858_L859del (on ENST00000231498 / NM_153485.3; = p.H799_L800del on NM_004298.4) | In Frame Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs1293965836; called by pindel, varscan2
- OBP2A | c.*2C>T | Splice Region (SNP) | VAF 12/63 reads (19%) | catalogued as rs1468912543; called by mutect2, varscan2
- PAN2 | c.3060G>T p.E1020D (on ENST00000425394 / NM_001127460.3; = p.E1016D on NM_014871.5) | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV56264315; called by muse, mutect2, varscan2
- POGK | c.57A>C p.E19D | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV63312606; called by muse, mutect2, varscan2
- PPP2R2B | c.184C>T p.H62Y (on ENST00000394409; = p.H128Y on NM_181674.2) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs746485595; called by muse, mutect2, varscan2
- PRSS36 | c.2148G>A p.W716* | Nonsense Mutation (SNP) | VAF 56/183 reads (31%) | catalogued as COSV51639674; called by muse, mutect2, varscan2
- SASH1 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66559224; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>A p.T910K | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV60785486, COSV60802491; called by muse, mutect2
- SORL1 | c.5186G>A p.R1729H | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs534646732, COSV52751649; called by muse, mutect2, varscan2
- STRN | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55745858; called by muse, mutect2, varscan2
- UBE3C | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.41); catalogued as rs528939743; called by muse, mutect2, varscan2
- UGT1A5 | c.460T>G p.F154V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs779404172; called by muse, mutect2, varscan2
- UTRN | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs868569544; called by muse, mutect2, varscan2
- ABCA13 | c.8410A>G p.S2804G | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY4 | c.2712G>C p.E904D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, varscan2
- ALG6 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AMH | c.271C>G p.R91G | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CABIN1 | c.3756C>G p.N1252K | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- DLG1 | c.2282A>G p.H761R (on ENST00000419354 / NM_001290983.1; = p.H783R on NM_004087.2) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DPPA4 | c.78G>T p.R26S | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2
- DSG4 | c.2620A>T p.N874Y | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FBLL1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- GLI3 | c.1273A>C p.S425R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- GUCY1A1 | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 171/400 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV2-70D | c.166A>C p.S56R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.513); called by muse, varscan2
- IGLV4-69 | c.50-2A>G p.X17_splice | Splice Site (SNP) | VAF 76/233 reads (33%) | called by muse, varscan2
- IGLV5-52 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KALRN | c.7711G>A p.A2571T (on ENST00000360013 / NM_001024660.4; = p.A874T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KBTBD6 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- KCNK15 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- LRRC71 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOTCH2 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUDT21 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.422); called by muse, mutect2
- PDE6A | c.627+1del p.X209_splice | Splice Site (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- POLD1 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SCARF1 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- SCN9A | c.3218A>G p.D1073G (on ENST00000303354; = p.D1062G on NM_002977.3) | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLCO6A1 | c.1729A>C p.K577Q | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPTAN1 | c.7146-4C>G | Splice Region (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- SPTBN4 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- URGCP-MRPS24 | c.*22A>G | Splice Region (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.642G>A p.L214= | Silent (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- DHCR24 | c.1320T>C p.Y440= | Silent (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- DIP2C | c.1485G>A p.A495= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs749520167, COSV55148699, COSV55178514; called by muse, mutect2, varscan2
- EDEM1 | c.132G>A p.Q44= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- EXOC3L1 | c.2127G>A p.P709= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- GABRG2 | c.321C>T p.I107= | Silent (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- GRM6 | c.297C>T p.C99= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- H1-2 | c.186G>T p.L62= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as COSV100642309, COSV59192116; called by muse, mutect2, varscan2
- IGHV2-70D | c.207T>A p.L69= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, varscan2
- KAT6B | c.3078G>A p.L1026= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- LYPD8 | c.541C>T p.L181= | Silent (SNP) | VAF 7/172 reads (4%) | called by muse, mutect2
- NLRC4 | c.2718C>T p.V906= | Silent (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
- NPFFR1 | c.792C>T p.R264= | Silent (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- NRXN3 | c.1449G>A p.S483= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as rs763322026; called by muse, mutect2, varscan2
- PCDHGC3 | c.1455C>T p.D485= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs1470454976; called by muse, mutect2, varscan2
- PEG3 | c.3873C>T p.F1291= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as rs747269638, COSV55631266, COSV99687637; called by muse, mutect2, varscan2
- PITPNM1 | c.3297C>T p.D1099= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as rs755856918; called by muse, mutect2
- RANBP17 | c.795C>T p.F265= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV66657123; called by muse, mutect2, varscan2
- REPIN1 | c.1629C>T p.F543= | Silent (SNP) | VAF 22/375 reads (6%) | called by muse, mutect2
- AC079612.1 | n.2276C>T | RNA (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.*487A>C | 3'UTR (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- ARL5B | c.*2705A>C | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2
- CACNA1E | c.*5991del | 3'UTR (DEL) | VAF 38/66 reads (58%) | called by mutect2, varscan2
- CERS6 | c.*2732A>C | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- COL5A2 | c.2391+100T>C | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- DCAF5 | c.*389A>T | 3'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- DISC1 | c.1981+48026G>T | Intron (SNP) | VAF 38/146 reads (26%) | catalogued as COSV64086005; called by muse, mutect2, varscan2
- DLX3 | c.*53C>T | 3'UTR (SNP) | VAF 36/80 reads (45%) | catalogued as rs1290770803; called by muse, mutect2, varscan2
- DOCK5 | c.168+2133del | Intron (DEL) | VAF 8/15 reads (53%) | catalogued as rs1232970189; called by mutect2, varscan2
- DPH2 | c.*352C>T | 3'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- EDEM3 | c.*2771C>G | 3'UTR (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- EGLN3 | c.*549C>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- FAM43A | c.*902G>A | 3'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs989592044; called by muse, mutect2
- FHL1 | c.*633A>G | 3'UTR (SNP) | VAF 40/50 reads (80%) | catalogued as rs1223549636; called by muse, mutect2, varscan2
- FKBP9 | c.-12C>G | 5'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- GCSAML | c.*2336G>T | 3'UTR (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- GLT1D1 | c.*839G>A | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- HAS1 | c.*12C>T | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs558430616, COSV99708213; called by muse, varscan2
- IGHV6-1 | c.-48A>C | 5'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- ISOC1 | c.*389T>C | 3'UTR (SNP) | VAF 54/87 reads (62%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*1712T>G | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- KMT2A | c.432+608dup | Intron (INS) | VAF 48/138 reads (35%) | called by mutect2, pindel, varscan2
- MED30 | c.-158C>T | 5'UTR (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- MIPOL1 | c.1262+23339C>G | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100539627; called by muse, mutect2
- NR1H4 | chr12:100499990 G>T | 5'Flank (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- OOSP2 | c.*727T>G | 3'UTR (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- OPRK1 | c.*3117C>T | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- POLK | c.2486-12T>A | Intron (SNP) | VAF 82/254 reads (32%) | called by muse, mutect2, varscan2
- POU3F3 | c.*1523G>A | 3'UTR (SNP) | VAF 7/76 reads (9%) | catalogued as rs1043826395; called by muse, mutect2, varscan2
- PPP1R12B | c.*5075A>G | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- PTPN7 | chr1:202160730 T>A | 5'Flank (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2
- SAMD4A | c.*172C>T | 3'UTR (SNP) | VAF 63/168 reads (38%) | called by muse, mutect2, varscan2
- SAMD4A | c.*1077C>T | 3'UTR (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- SAMHD1 | c.*1963del | 3'UTR (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- SEPTIN6 | chrX:119616475 C>T | 3'Flank (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- SGTA | c.*403G>A | 3'UTR (SNP) | VAF 12/21 reads (57%) | catalogued as rs973952049; called by muse, mutect2, varscan2
- SLC35G6 | c.*18C>T | 3'UTR (SNP) | VAF 12/56 reads (21%) | catalogued as rs372053590; called by muse, mutect2
- SLC4A11 | c.1463+79G>A | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs1452055557; called by muse, mutect2, varscan2
- ST8SIA3 | c.-68C>T | 5'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as rs1224547736, COSV100129763; called by muse, mutect2, varscan2
- ST8SIA4 | c.*396C>G | 3'UTR (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- TMEM167A | c.*3208A>G | 3'UTR (SNP) | VAF 11/283 reads (4%) | called by muse, mutect2
- TMPO | c.*726T>C | 3'UTR (SNP) | VAF 5/28 reads (18%) | catalogued as rs946396179; called by muse, mutect2, varscan2
- TMX3 | c.-111C>A | 5'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- TRAT1 | c.*379G>A | 3'UTR (SNP) | VAF 13/42 reads (31%) | catalogued as rs540625575; called by muse, mutect2, varscan2
- UGT2A1 | c.*26_*27dup | 3'UTR (INS) | VAF 6/38 reads (16%) | catalogued as rs961495032, COSV99684478; called by mutect2, varscan2
- UNC5C | c.*5759T>G | 3'UTR (SNP) | VAF 3/37 reads (8%) | catalogued as rs887824966; called by muse, mutect2
- WNT5A | c.*1169A>G | 3'UTR (SNP) | VAF 7/83 reads (8%) | catalogued as rs947145211; called by muse, mutect2
- ZBTB34 | c.*4327T>C | 3'UTR (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- ZNF33A | c.*1551A>T | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- ZNF829 | c.*223C>T | 3'UTR (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.*954_*976del | 3'UTR (DEL) | VAF 6/28 reads (21%) | called by pindel, varscan2*
